Surgical pathology report (de-identified scan), TCGA case TCGA-BJ-A28S, project TCGA-THCA (Thyroid Carcinoma), tissue source site University of Pittsburgh, specimen TCGA-BJ-A28S-01A (Primary Tumor).

PATIENT HISTORY:

CHIEF COMPLAINT/PRE-OP/POST-OP DIAGNOSIS: Thyroid nodule.

PROCEDURE: not answered.

SPECIFIC CLINICAL QUESTION: Not answered

OUTSIDE TISSUE DIAGNOSIS: Not answered.

PRIOR MALIGNANCY: Not answered.

CHEMOTHERAPY: Not answered.

ORGAN TRANSPLANT: Not answered.

IMMUNOSUPPRESSION: Not answered.

OTHER DISEASES: Not answered.

ADDENDA:**Addendum**

1CD-0-3
carcinoma, papillary, follicular variant
8340/3

Site: thyroid C13.9

hw
5/25/11**MOLECULAR ANATOMIC PATHOLOGY TESTING:****Block B (Right lobe):**

Collection Date:

- A. Mutations in *HRAS61* NOT identified.
- B. Mutational analysis of *BRAF*, *NRAS61*, *KRAS12/13* is INDETERMINATE due to poor quality of isolated DNA (see note).
- C. FISH for *RET/PTC* rearrangement is pending.

Block D (Left lobe lesion):

- A. Mutations in *HRAS61* and *KRAS 12/13* NOT identified.
- B. Mutational analysis of *BRAF* and *NRAS61* is INDETERMINATE due to poor quality of isolated DNA (see note).
- C. FISH for *RET/PTC* rearrangement is pending.

FINAL DIAGNOSIS:

THYROID GLAND, TOTAL THYROIDECTOMY (30 GRAMS) -

- A. TWO FOCI OF PAPILLARY THYROID CARCINOMA: 3.4 CM ENCAPSULATED FOLLICULAR VARIANT IN LEFT LOBE, AND 0.5 CM ENCAPSULATED FOLLICULAR VARIANT IN RIGHT LOBE (see comment).
- B. NO TUMOR CAPSULE INVASION, ANGIOLYMPHATIC INVASION, OR EXTRATHYROIDAL EXTENSION IS IDENTIFIED.
- C. ALL RESECTION MARGINS ARE NEGATIVE.
- D. AJCC TUMOR STAGE pT2NX.

COMMENT:

Both tumors are encapsulated and show no invasive growth. Molecular testing has been ordered on both tumor foci, and results will be reported in an addendum.

CASE SYNOPSIS:**SYNOPTIC DATA - PRIMARY THYROID TUMORS**

SPECIMEN TYPE:

Total Thyroidectomy

TUMOR SITE:

Right Lobe, Left Lobe

TUMOR FOCALITY:

Multifocal

TUMOR SIZE (largest nodule):

Greatest Dimension: 3.4 cm

HISTOLOGIC TYPE**:

Papillary carcinoma, encapsulated follicular variant

PRIMARY TUMOR (pT):

pT2

REGIONAL LYMPH NODES (pN):

pNX

Number of regional lymph nodes examined: 0

Number of regional lymph nodes involved: 0

DISTANT METASTASIS (pM):

Not applicable

EXTRATHYROIDAL EXTENSION:

Not identified

MARGINS:

Margins uninvolved by carcinoma

LYMPH-VASCULAR INVASION:

Not identified

ADDITIONAL PATHOLOGIC FINDINGS:

None Identified

Diagnostic Discrepancy		X
III+AA Discrepancy		X

Source: NCI Genomic Data Commons file bc3cd092-d103-4edc-a218-a876cd04057b (TCGA-BJ-A28S.65955922-11C7-4627-BE4B-EDF0886B86B4.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).